Somatic mutation profile of tumor specimen TCGA-SC-A6LN-01A (aliquot TCGA-SC-A6LN-01A-11D-A34C-32) from TCGA case TCGA-SC-A6LN, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mesothelioma, biphasic, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 76.4 years (27,917 days).
Specimen TCGA-SC-A6LN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0e70a44-9281-4866-ad48-c8630c07fdd2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SC-A6LN-10A (Blood Derived Normal), aliquot TCGA-SC-A6LN-10A-01D-A34C-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/92d86ae9-0d3f-4089-b40b-c8784312ed40

The open-access MAF lists 32 somatic variants for this specimen: 22 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 9, Frame Shift Del 3, In Frame Del 2, Nonsense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC10 | c.1709G>A p.R570Q (on ENST00000372530 / NM_001198934.2; = p.R527Q on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/53 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745844891, COSV55085418; called by muse, mutect2, varscan2
- AGRN | c.4624G>C p.G1542R | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV65069985; called by muse, mutect2, varscan2
- DNLZ | c.283G>A p.V95M | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781401965; called by muse, mutect2, varscan2
- EIF2A | c.470A>G p.N157S | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as rs202127297; called by muse, mutect2, varscan2
- EXOG | c.638_641del p.S213Tfs*3 | Frame Shift Del (DEL) | VAF 21/109 reads (19%) | catalogued as rs771911750; called by pindel, varscan2
- JPH3 | c.1565G>A p.R522Q | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.297); catalogued as rs748590824; called by muse, mutect2, varscan2
- PLEKHG4 | c.1892G>A p.R631Q | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs760420600; called by muse, mutect2, varscan2
- PPP1R15B | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.503); catalogued as rs1479359138; called by muse, mutect2, varscan2
- STAG2 | c.647G>T p.R216L | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV54357904; called by mutect2, varscan2
- WDR75 | c.746A>G p.D249G | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.033); catalogued as rs779064956; called by muse, mutect2, varscan2
- ANO2 | c.658A>T p.K220* (on ENST00000356134 / NM_001278597.3; = p.K224* on NM_001278596.3) | Nonsense Mutation (SNP) | VAF 13/37 reads (35%) | called by muse, mutect2, varscan2
- AP002748.5 | c.1663C>G p.L555V | Missense Mutation (SNP) | VAF 48/207 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CDK11B | c.1630_1635del p.I544_Q545del | In Frame Del (DEL) | VAF 6/17 reads (35%) | called by mutect2, varscan2
- CHD6 | c.1207del p.C403Afs*12 | Frame Shift Del (DEL) | VAF 23/100 reads (23%) | called by mutect2, pindel, varscan2
- EXOG | c.854A>T p.D285V | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- KCNH3 | c.2790C>A p.S930R | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- KPTN | c.902T>A p.L301Q | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LASP1 | c.751G>A p.G251R | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MICAL1 | c.1327_1328del p.L443Vfs*41 | Frame Shift Del (DEL) | VAF 36/118 reads (31%) | called by mutect2, pindel, varscan2
- MSH3 | c.469C>T p.Q157* | Nonsense Mutation (SNP) | VAF 8/22 reads (36%) | called by muse, mutect2, varscan2
- NEB | c.13429T>C p.Y4477H | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OTUD7B | c.78_80del p.L27del | In Frame Del (DEL) | VAF 20/121 reads (17%) | called by mutect2, pindel, varscan2
- ANKRD11 | c.5349C>G p.L1783= | Silent (SNP) | VAF 49/178 reads (28%) | called by muse, mutect2, varscan2
- ATL3 | c.1485A>G p.Q495= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs1002281378; called by muse, mutect2, varscan2
- CDK13 | c.3282T>C p.I1094= | Silent (SNP) | VAF 14/64 reads (22%) | called by muse, mutect2, varscan2
- HSPG2 | c.2523C>T p.A841= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as COSV65976276; called by muse, mutect2, varscan2
- JHY | c.2256C>A p.I752= | Silent (SNP) | VAF 38/156 reads (24%) | called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1086C>T p.D362= (on ENST00000352766; = p.D283= on NM_181334.5) | Silent (SNP) | VAF 36/73 reads (49%) | catalogued as rs753961460; called by muse, mutect2, varscan2
- SLC6A7 | c.1663C>T p.L555= | Silent (SNP) | VAF 14/37 reads (38%) | called by muse, mutect2, varscan2
- TRAF7 | c.1464A>G p.S488= | Silent (SNP) | VAF 14/41 reads (34%) | called by muse, mutect2, varscan2
- ZNF341 | c.1365C>T p.S455= (on ENST00000375200 / NM_001282935.1; = p.S448= on NM_032819.4) | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as rs373030676; called by muse, mutect2, varscan2
- CTBP2 | c.58+12134G>A | Intron (SNP) | VAF 22/89 reads (25%) | catalogued as rs770507202, COSV58344748; called by muse, mutect2, varscan2
